TCGA case TCGA-BR-6705 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b14f2fcb-e869-475e-bc7c-adaf6e7e636f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Ukraine; Age at index: 68 years; Vital status: Dead; Days to death: 779 days (2.1 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.2; Tissue or organ of origin: Body of stomach; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 68.6 years (25,073 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N3a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 779 days (2.1 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 9; Lymph nodes tested: 12.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 53 days; Disease response: Tumor Free.
- Days to follow up: 421 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 779 days (2.1 years); Disease response: With Tumor.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BR-6705-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.8; Intermediate dimension: 1.2; Shortest dimension: 0.6.
  Slide TCGA-BR-6705-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25.
  Slide TCGA-BR-6705-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
- Sample TCGA-BR-6705-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BR-6705-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Fundus/Body; Lymph nodes examined: Yes; Cancer procurement city: Kiev; Number of relatives with stomach cancer: 0.
- Follow-up form 1: New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Progressive Disease; Cause of death: Stomach Cancer.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 779 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 779 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 779 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BR-6705-01A-12D-1881-01): tumor purity 0.17, ploidy 2.14, whole-genome doublings 0.
